Surgical pathology report (de-identified scan), TCGA case TCGA-50-6597, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-6597-01A (Primary Tumor).

[page 1 of 2]
PATIENT HISTORY:

PRE-OP DIAGNOSIS: Lung cancer (right lung).
POST-OP DIAGNOSIS: Same.
PROCEDURE: Bronchoscopy, mediastinoscopy and thoracotomy.

ADDENDA:

Addendum

Molecular Anatomic Pathology Microdissection Genotyping Testing:

- A. *KRAS* Exon 1 mutation NOT identified.
- B. *EGFR* Exon 19 mutation NOT identified.
- C. *EGFR* Exon 21 mutation NOT identified.

Note:

KRAS codon 12/13 mutations are found in approximately 10-30% lung adenocarcinomas and associated with history of smoking (1). *EGFR* exon 19 and 21 mutations are present in about 10% of non-Asians and up to 40% in the Asian population, common in non-smokers and associated with the tumor response to treatment with *EGFR* inhibitors (2). These mutations are mutually exclusive and their presence may have prognostic and/or therapeutic implications (3,4).

Addendum

PROBE: Vysis LSI *EGFR* SpectrumOrange/ CEP 7 SpectrumGreen™ Probe

Fluorescence in-situ hybridization studies performed on the adenocarcinoma shows a ratio of *EGFR* gene to the centromere of chromosome 7 of 1.07 indicating **no *EGFR* amplification** in the targeted region. The rate of hyperploidy for the centromere of chromosome 7 was 30% of the analyzed cells. The signal to nucleus ratio (SNR) for the *EGFR* gene was 2.5. 60 cells were analyzed in the targeted region.

Interpretation guidelines for *EGFR* Gene Copy Number by FISH:

Ratio of *EGFR* to the centromere of chromosome 7:

- Less than 2.0: No *EGFR* amplification
- Greater than 2.0: *EGFR* amplification

Hyperploidy: Greater than two centromere copies/cell.

SNR: The average number of *EGFR* signals per analyzed cell within the targeted region.

Clinical studies show high *EGFR* gene copy number by FISH analysis to be associated with favorable clinical benefit (clinical response, stable disease, time to progression, and survival) in patients with advanced non-small cell lung cancer treated with *EGFR* tyrosine kinase inhibitors.

FINAL DIAGNOSIS:

Summary Statement

The right lower lobe superior segment demonstrates a 2.5 cm invasive moderately differentiated adenocarcinoma associated with visceral pleural and angiolymphatic invasion. All sampled lymph nodes are benign. Surgical resection margins are free of tumor. The pathologic stage is T2N0Mx.

The right middle lobe demonstrates a 0.6 cm typical carcinoid. Numerous carcinoid tumorlets and diffuse neuroendocrine cell hyperplasia are seen throughout the right upper, right lower and right middle lobes.

PART 1: LYMPH NODE, SUBCARINAL, BIOPSY –

FIVE (5) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 2: LYMPH NODES, RIGHT TB ANGLE, BIOPSY –

THREE (3) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 3: LYMPH NODES, LEFT TB ANGLE, BIOPSY –

TWO (2) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 4: LYMPH NODES, LEFT PARATRACHEAL, BIOPSY –

TWO (2) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

[page 2 of 2]
PART 5: LYMPH NODE, RIGHT PARATRACHEAL, BIOPSY –
ONE (1) LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 6: LYMPH NODES, SUBINOMINATE, BIOPSY –
TWO (2) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 7: LYMPH NODES, POSTERIOR HILAR, BIOPSY –
TWO (2) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 8: LYMPH NODES, ANTERIOR HILAR, BIOPSY –
TWO (2) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 9: LYMPH NODE, INTRALOBAR LOBE, BIOPSY –
ONE (1) LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 10: LYMPH NODES, RIGHT LOWER LOBE / SUPERIOR SEGMENT, BIOPSY –
TWO (2) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 11: LUNG, RIGHT LOWER LOBE SUPERIOR SEGMENT, SUPERIOR SEGMENTECTOMY –

- A. INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA (2.5 CM IN DIAMETER) ARISING IN A SCAR AND ASSOCIATED WITH ANGIOLYMPHATIC AND VISCERAL PLEURAL INVASION. MODERATE LYMPHOCYTIC HOST RESPONSE. PATHOLOGIC STAGE: T2N0MX.
- B. SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
- C. BACKGROUND LUNG WITH EMPHYSEMATOUS CHANGE, CALCIFIED NODULE, AND MULTIPLE CARCINOID TUMORLETS.

PART 12: LUNG, RIGHT UPPER LOBE, WEDGE BIOPSY –
LUNG PARENCHYMA WITH MILD EMPHYSEMATOUS CHANGE AND DUST MACULES.

PART 13: LUNG, RIGHT UPPER LOBE, WEDGE BIOPSY –
LUNG PARENCHYMA WITH CARCINOID TUMORLET AND MILD EMPHYSEMATOUS CHANGE.

PART 14: LUNG, RIGHT LOWER LOBE, WEDGE BIOPSY –
LUNG PARENCHYMA WITH MILD EMPHYSEMATOUS CHANGE.

PART 15: LUNG, RIGHT MIDDLE LOBE, WEDGE BIOPSY –
TYPICAL CARCINOID (0.6 CM IN DIAMETER), ASSOCIATED WITH CARCINOID TUMORLETS AND NEUROENDOCRINE CELL HYPERPLASIA. (See comment).

COMMENT:

This case in addition to invasive moderately differentiated adenocarcinoma demonstrates typical carcinoid in the right middle lobe associated with numerous carcinoid tumorlets and diffuse neuroendocrine cell hyperplasia. A primary lung origin of carcinoid is confirmed by positive TTF-1 and synaptophysin immunostaining. CDX2 and calcitonin are negative. Surgical resection margin of the right middle lobe demonstrates scattered small microscopic foci of neuroendocrine cells. However, based on the gross description it seems that margin is negative for tumor and these neuroendocrine cells may represent another focus of tumorlet.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY LUNG TUMORS

TUMOR LOCATION:	Right Lower Lobe
LUNG SEGMENT(S) INVOLVED:	Superior
PROCEDURE:	Segmental
TUMOR SIZE:	Maximum dimension: 2.5 cm Minor dimension: 0.9 cm
GROSS SATELLITES:	Number of gross satellite lesions: 0
TUMOR TYPE:	Invasive adenocarcinoma, Carcinoid
HISTOLOGIC GRADE:	G2, Moderately differentiated
MICROSCOPIC SATELLITES:	Number of microscopic satellite lesions: 0
EXTRAPULMONARY PARENCHYMAL	
EXTENSION/INVASION OF TUMOR:	Visceral pleura
ANGIOLYMPHATIC INVASION:	Yes
TUMOR NECROSIS:	< or = to 50%
SURGICAL MARGIN INVOLVEMENT:	No
SURGICAL MARGIN SITE:	Distance of invasive tumor to closest margin: 12 mm, Parenchymal margin
INFLAMMATORY(DESMOPLASTIC) REACTION:	Moderate
N1 LYMPH NODES:	Number of N1 lymph nodes positive: 0 Number of N1 lymph nodes examined: 7
EXTRACAPSULAR SPREAD OF N1 METASTASES:	No
N2 LYMPH NODES:	Number of N2 lymph nodes positive: 0 Number of N2 lymph nodes examined: 15
UNDERLYING DISEASE(S):	Emphysema, Parenchymal scar, Tumorlets
T STAGE, PATHOLOGIC:	pT2
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
ANCILLARY STUDIES:	Histochemical stains, Immunohistochemical stains, FISH studies, Molecular studies

Source: NCI Genomic Data Commons file 0c79ae98-7228-40b2-b1cf-28ca60951079 (TCGA-50-6597.6BA1EE6A-B37E-4F8D-9435-3D69AD1DBFDD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).